Somatic mutation profile of tumor specimen TCGA-XE-AANV-01A (aliquot TCGA-XE-AANV-01A-11D-A435-10) from TCGA case TCGA-XE-AANV, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 52.3 years (19,112 days).
Specimen TCGA-XE-AANV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68b0feda-3eac-4008-b359-6391c3352754.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XE-AANV-10A (Blood Derived Normal), aliquot TCGA-XE-AANV-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/601de95c-32fc-456a-b7ea-db740dbc780f

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAC1 | c.101C>G p.P34R | Missense Mutation (SNP) | VAF 18/133 reads (14%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV61822860, COSV61823271; called by muse, mutect2, varscan2
- CEP170B | c.3020A>G p.Q1007R (on ENST00000453495; = p.Q936R on NM_015005.3) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753031175; called by muse, mutect2
- KIT | c.1733A>G p.Y578C | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55393841, COSV55414237; called by muse, mutect2, varscan2
- KIT | c.2474T>A p.V825D | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55389004; called by muse, mutect2, varscan2
- PREX1 | c.2067C>A p.N689K | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV64250247; called by muse, mutect2
- PRR35 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV53462712; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4808A>G p.N1603S | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ADGRV1 | c.3990del p.F1330Lfs*4 | Frame Shift Del (DEL) | VAF 24/152 reads (16%) | called by mutect2, pindel, varscan2
- GATA3 | c.1119A>C p.K373N | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR2T34 | c.607C>G p.L203V | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TYRO3 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- DPYD | c.2043C>A p.G681= | Silent (SNP) | VAF 29/190 reads (15%) | called by muse, mutect2, varscan2
- EIF4E | c.180G>A p.L60= | Silent (SNP) | VAF 41/220 reads (19%) | called by muse, mutect2, varscan2
- RBM20 | c.1785G>A p.K595= | Silent (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
